Gene-level copy-number profile of tumor specimen ALCH-B2RQ-TTP1-A from ALCHEMIST case ALCH-B2RQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.7 years (20,347 days).
Specimen ALCH-B2RQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3b151496-df7c-4b83-8b55-4f8d24c699ac.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2RQ-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/175b1bdf-ef1b-44db-af43-52700bb9c71e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 241; copy number 1: 18,956; copy number 2: 32,072; copy number 3: 6,489; copy number 4: 153; copy number 5: 194; copy number 6: 795; copy number 11: 2; copy number 32: 3.

Homozygous deletions (total copy number 0; autosomes only): 240 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:1,027,678–1,028,972, 1 gene: AC019103.1.
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:4,775,615–4,794,397, 3 genes: AP5Z1, MIR4656, AC092610.1.
- chr7:4,811,188–4,811,289, 1 gene (within-gene range 0–2): Y_RNA.
- chr9:21,231,266–26,644,595, 61 genes (broad region; genes not listed).
- chr13:19,182,038–19,187,618, 1 gene: AL139327.1.
- chr16:15,104,312–15,154,564, 5 genes (within-gene range 0–2): NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA.
- chr17:18,497,095–18,551,705, 4 genes (within-gene range 0–1): NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr21:9,975,017–10,137,004, 4 genes: CR382285.1, CR382285.2, CR382287.1, CDRT15P8.
- chr21:13,305,152–22,420,819, 143 genes (broad region; genes not listed).
- chr22:18,615,581–18,625,289, 2 genes: Metazoa_SRP, SUSD2P2.
- chr22:18,773,665–18,843,399, 3 genes (within-gene range 0–2): GGT3P, AC008132.2, E2F6P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 994 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:138,261,437–142,149,544, 76 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr3:145,523,538–198,123,232, 912 genes, copy number 5–6 (broad region; genes not listed).
- chr22:18,733,914–18,757,906, 1 gene, copy number 6: FAM230E.
- chr22:18,873,543–18,947,732, 5 genes, copy number 11–32 (within-gene range 3–32): FAM230F, AC008103.1, DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 16,106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
